TCGA case TCGA-D1-A16G — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16e69011-c295-479f-b521-86e66fba498d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 834 days (2.3 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 74.1 years (27,065 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; FIGO stage: Stage IV; FIGO staging edition year: 1995; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 15.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 100.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 30.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 67 days; Days to treatment end: 67 days; Number of cycles: 1; Treatment dose: 480 mg; Prescribed dose: 5; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 67 days; Days to treatment end: 67 days; Number of cycles: 1; Treatment dose: 250 mg; Prescribed dose: 135; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 185 days; Number of cycles: 5; Treatment dose: 2,730 mg; Prescribed dose: 6; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 185 days; Number of cycles: 5; Treatment dose: 1,600 mg; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 220 days; Days to treatment end: 257 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Adjuvant; Days to treatment start: 243 days; Days to treatment end: 250 days; Treatment dose: 1,100 cGy; Course number: 1; Number of fractions: 2; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 651 days (1.8 years); Days to treatment end: 756 days (2.1 years); Number of cycles: 6; Treatment dose: 2,770 mg; Prescribed dose: 5; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 651 days (1.8 years); Days to treatment end: 756 days (2.1 years); Number of cycles: 6; Treatment dose: 1,470 mg; Prescribed dose: 135; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Initial disease status: Recurrent Disease; Days to treatment start: 794 days (2.2 years); Days to treatment end: 822 days (2.3 years); Number of cycles: 2; Treatment dose: 145 mg; Prescribed dose: 40; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Lymph node, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 75.9 years (27,707 days); Days to diagnosis: 642 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 642 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS.
- Days to follow up: 834 days (2.3 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 173 cm; BMI: 25.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D1-A16G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-D1-A16G-01A-03-TS3: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 30.
- Sample TCGA-D1-A16G-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D1-A16G-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; History tamoxifen use: Never Used; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: Yes; New tumor event site other: Lymph nodes; New tumor event type: Locoregional Disease; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 4; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Regimen number: 3; Pharmaceutical therapy drug name: Taxol; Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 834 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 834 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 642 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D1-A16G-01A-31D-A12G-01): tumor purity 0.36, ploidy 4.05, whole-genome doublings 1.
